Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BU, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BU-01A (Primary Tumor).

10/15/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1) THYROID AND CENTRAL NECK SOFT TISSUE (TOTAL THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Right lobe, isthmus, left lobe

HISTOLOGIC TYPE: Papillary carcinoma

100-0-3

Carcinoma, papillary, thyroid 8260/3
Site: thyroid, Nos C73.9

FOCALITY: Multifocal

Left lobe: 1.4 cm

Isthmus: 0.2 cm

Right lobe: 0.3 cm

hw
10/15/11

LYMPH NODES (ALL PARTS):

Metastatic carcinoma in 6 of 9 lymph nodes

EXTENT OF INVASION (STAGING) PRIMARY TUMOR:

pT1: Tumor size less than or equal to 2.0 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS: Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Indeterminate

ADDITIONAL PATHOLOGIC FINDINGS:

Nodular hyperplasia

Source: NCI Genomic Data Commons file 75845567-a0d6-4c19-8910-b9d027727416 (TCGA-ET-A3BU.5267B76A-3EFC-4B17-818D-FE8D97C4F3DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).